TCGA case TCGA-5R-AA1C — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Proteogenex, Inc. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/290890eb-321c-45dc-9cd1-45676c6e5e96

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 57.7 years (21,073 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 520 days (1.4 years); Child pugh classification: B; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 63 days; Disease response: Tumor Free.
- Days to follow up: 364 days; Disease response: Tumor Free.
- ECOG performance status: 1.
- Follow-up contact recording only the day: day 520.

Molecular and laboratory tests
- Alpha Fetoprotein 2 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 15].
- Albumin 3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.2; Blood test normal range upper: 4.6].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.3].
- Platelets 223000 (unit not recorded by GDC) [Blood test normal range lower: 150000; Blood test normal range upper: 450000].
- Total Bilirubin 1.8 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Prothrombin Time 18 Seconds [Blood test normal range lower: 11; Blood test normal range upper: 15].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 174 cm; BMI: 29.7.
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / Hepatitis C Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5R-AA1C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 750 mg.
  Slide TCGA-5R-AA1C-01A-01-TS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 4; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-5R-AA1C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-5R-AA1C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Extended Lobectomy; New tumor event diagnosis indicator: No.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 520 days; disease-specific survival: no event (censored), 520 days; disease-free interval: no event (censored), 520 days; progression-free interval: no event (censored), 520 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-5R-AA1C-01A-11D-A40Q-01): tumor purity 0.85, ploidy 2.28, whole-genome doublings 0.
